Somatic mutation profile of tumor specimen TCGA-2G-AAG3-01A (aliquot TCGA-2G-AAG3-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAG3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 53.6 years (19,583 days).
Specimen TCGA-2G-AAG3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58731e2d-a07c-46f3-852b-fa9db4ec217a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG3-10A (Blood Derived Normal), aliquot TCGA-2G-AAG3-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0d270d0-72c5-4775-8d4d-4194e9a3c7d4

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 14/194 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2
- ACSM2B | c.1239G>T p.R413S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV100313015; called by muse, mutect2, varscan2
- NEK10 | c.3453C>A p.Y1151* | Nonsense Mutation (SNP) | VAF 123/327 reads (38%) | catalogued as rs768169562; called by muse, mutect2, varscan2
- ODF3 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs752294657, COSV57292599; called by muse, mutect2, varscan2
- ARMCX5 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ATL2 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- AVIL | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CFAP206 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.228); called by muse, mutect2
- JARID2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- KCNE4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PELP1 | c.3314C>A p.T1105K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- VPS33A | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBAG9 | c.360C>A p.I120= | Silent (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- ILF3 | c.2175G>A p.P725= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs1259844053; called by muse, mutect2, varscan2
- SHANK2 | c.1569C>T p.Y523= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs888204009; called by muse, mutect2, varscan2
- TMEM182 | c.249C>G p.S83= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- ZHX1 | c.516T>C p.S172= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as rs1381616362; called by muse, mutect2, varscan2
